Gene-level copy-number profile of tumor specimen TCGA-FP-A4BF-01A from TCGA case TCGA-FP-A4BF, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 68.5 years (25,030 days).
Specimen TCGA-FP-A4BF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.5e29e8ee-07aa-44fc-87e8-486dca384053.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FP-A4BF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5f43606e-db9d-4433-9032-ce517d7e0111

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 518; copy number 2: 2,148; copy number 3: 17,445; copy number 4: 7,267; copy number 5: 22,236; copy number 6: 3,679; copy number 7: 2,757; copy number 8: 750; copy number 9: 1,336; copy number 10: 766; copy number 11: 341; copy number 12: 24; copy number 13: 2; copy number 14: 270; copy number 15: 53; copy number 20: 40; copy number 23: 152; copy number 90: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FP-A4BF-01A-12D-A24C-01): tumor purity 0.28, ploidy 4.15, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,856,605, 6 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr16:78,495,926–78,892,302, 8 genes: AC046158.1, AC046158.4, AC046158.2, AC046158.3, AC009141.1, RPS3P7, AC136603.1, AC027279.4.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 896 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,019,656–148,288,951, 47 genes, copy number 15 (within-gene range 8–15): AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2, RNVU1-22, LINC01731, AC245100.3.
- chr1:148,295,180–148,344,638, 6 genes, copy number 15: LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21.
- chr1:153,561,108–154,628,013, 73 genes, copy number 14 (within-gene range 5–14) (broad region; genes not listed).
- chr1:160,739,057–161,728,143, 66 genes, copy number 14 (broad region; genes not listed).
- chr4:139,015,781–148,444,698, 150 genes, copy number 23 (within-gene range 3–23) (broad region; genes not listed).
- chr4:148,526,493–148,558,048, 2 genes, copy number 23: ASS1P8, RNA5SP166.
- chr6:147,508,690–147,737,547, 1 gene, copy number 13: SAMD5.
- chr6:147,741,434–147,743,324, 1 gene, copy number 13: AL365271.1.
- chr7:40,135,005–40,860,763, 1 gene, copy number 11 (within-gene range 6–11): SUGCT.
- chr7:40,538,127–40,785,217, 2 genes, copy number 11: SUGCT-AS1, AC005160.1.
- chr7:54,621,025–56,675,086, 78 genes, copy number 12–90 (broad region; genes not listed).
- chr8:135,859,369–138,497,261, 11 genes, copy number 11 (within-gene range 10–11): LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B.
- chr19:38,108,500–41,207,539, 173 genes, copy number 11–14 (broad region; genes not listed).
- chr20:44,106,590–56,269,231, 285 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 507. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
